Gene-level copy-number profile of tumor specimen TCGA-LN-A9FQ-01A from TCGA case TCGA-LN-A9FQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 62.2 years (22,717 days).
Specimen TCGA-LN-A9FQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.044a1dc4-f089-4df1-aa44-87cd2859d8cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A9FQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45a0c4c1-94a7-427e-9cb9-a78ea02a7585

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2,201; copy number 2: 13,272; copy number 3: 19,516; copy number 4: 16,013; copy number 5: 1,778; copy number 6: 4,599; copy number 7: 1,208; copy number 8: 1,047; copy number 9: 25; copy number 10: 7; copy number 11: 91; copy number 13: 6; copy number 15: 12; copy number 34: 18; copy number 38: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A9FQ-01A-31D-A386-01): tumor purity 0.78, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr9:21,802,636–22,214,672, 15 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,416 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:169,792,529–171,251,857, 31 genes, copy number 7 (within-gene range 6–7): METTL18, SCYL3, RN7SL333P, AL031297.1, KIFAP3, RN7SL269P, MRPS10P1, AL356475.1, SIGLEC30P, METTL11B, MIR3119-2, MIR3119-1, LINC01681, ISCUP1, LINC01142, HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1.
- chr1:184,999,710–199,752,890, 160 genes, copy number 7 (broad region; genes not listed).
- chr1:225,401,502–248,919,946, 597 genes, copy number 8–9 (broad region; genes not listed).
- chr2:101,962,056–104,077,778, 31 genes, copy number 7 (within-gene range 6–7): LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3.
- chr2:113,325,372–123,763,071, 127 genes, copy number 7–13 (broad region; genes not listed).
- chr3:143,265,222–143,848,485, 1 gene, copy number 7 (within-gene range 6–7): SLC9A9.
- chr3:143,503,275–155,183,704, 174 genes, copy number 7 (broad region; genes not listed).
- chr3:161,816,909–175,810,548, 151 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:187,217,282–192,767,764, 62 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:40,161,458–40,897,833, 5 genes, copy number 11 (within-gene range 2–11): AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4.
- chr8:41,929,479–43,085,788, 32 genes, copy number 15–38 (within-gene range 14–38): KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P.
- chr8:117,794,490–145,066,685, 486 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr9:14,475–13,323,450, 173 genes, copy number 7 (broad region; genes not listed).
- chr9:13,406,380–13,488,125, 1 gene, copy number 7: LINC01235.
- chr10:36,626,015–37,384,111, 12 genes, copy number 8: Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P.
- chr14:22,982,698–23,729,757, 43 genes, copy number 8 (within-gene range 4–8): AL132780.2, C14orf93, AL132780.5, PSMB5, AL132780.4, PSMB11, CDH24, ACIN1, C14orf119, LMLN2, CEBPE, SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1, JPH4, AL135999.3, DHRS2, AL160237.1.
- chr17:49,132,460–59,892,945, 264 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:976,589–2,489,426, 12 genes, copy number 7–10 (within-gene range 2–10): AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3.
- chr20:87,250–1,002,311, 27 genes, copy number 7: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4.
- chr20:10,996,293–13,368,703, 27 genes, copy number 7: LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1.

Autosomal genes at a single copy (total copy number 1): 702. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
